Somatic mutation profile of tumor specimen MMRF_2327_1_BM_CD138pos (aliquot MMRF_2327_1_BM_CD138pos_T1_KHS5U_L11245) from MMRF case MMRF_2327, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 73.4 years (26,820 days).
Specimen MMRF_2327_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b85887a-75c3-4071-962c-40e2dc7b2215.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2327_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2327_1_PB_WBC_C2_KHS5U_L11246; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56d89362-3d9c-4861-8267-3532c3ca174c

The open-access MAF lists 126 somatic variants for this specimen: 61 protein-altering or splice-affecting, 11 silent, 54 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, 3'UTR 24, Intron 17, Silent 11, 5'Flank 5, Splice Region 3, Frame Shift Del 3, 3'Flank 3, Nonsense Mutation 3, 5'UTR 3, Splice Site 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 44/219 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CLEC5A | c.339G>T p.E113D | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.136); catalogued as COSV69398122; called by muse, mutect2, varscan2
- DNAH9 | c.5981C>T p.A1994V | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104389664; called by muse, mutect2, varscan2
- FLNB | c.3637G>A p.V1213M | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760397310; called by muse, mutect2, varscan2
- HGF | c.1480C>T p.R494* | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | catalogued as COSV55956894; called by muse, mutect2, varscan2
- IGLV3-1 | c.50C>A p.S17Y | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as rs184648956; called by muse, varscan2
- LAMA2 | c.7826T>C p.I2609T | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.164); catalogued as rs752806166; called by muse, mutect2, varscan2
- MTSS2 | c.2111C>T p.T704M | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs547904006, COSV55381548; called by muse, mutect2, varscan2
- PAK3 | c.1071G>A p.M357I (on ENST00000262836 / NM_001324328.2; = p.M342I on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1228989985; called by muse, mutect2, varscan2
- RHOXF1 | c.16G>A p.V6I | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as rs931167506, COSV99483843; called by muse, mutect2, varscan2
- ROBO1 | c.3730C>T p.R1244W | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs372853961; called by muse, mutect2, varscan2
- SPC24 | c.410+1G>T p.X137_splice | Splice Site (SNP) | VAF 49/301 reads (16%) | catalogued as COSV104436937; called by muse, mutect2, varscan2
- SPRR1B | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.779); catalogued as COSV100198445; called by muse, mutect2, varscan2
- TM4SF1 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 121/300 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.59); catalogued as rs745533363, COSV59524833; called by muse, mutect2, varscan2
- VCAM1 | c.829A>C p.T277P | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54119763; called by muse, mutect2, varscan2
- ZC3H18 | c.1204C>T p.R402* | Nonsense Mutation (SNP) | VAF 17/62 reads (27%) | catalogued as COSV56324075; called by muse, mutect2, varscan2
- ZFHX4 | c.8221G>A p.D2741N | Missense Mutation (SNP) | VAF 40/215 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.736); catalogued as COSV99264255; called by muse, mutect2, varscan2
- ARHGAP28 | c.1396C>A p.L466I (on ENST00000383472 / NM_001366230.1; = p.L307I on NM_001010000.3) | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASIC5 | c.523T>G p.F175V | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- ATG2B | c.1228A>T p.M410L | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- CCDC183 | c.1499del p.F500Sfs*22 | Frame Shift Del (DEL) | VAF 23/110 reads (21%) | called by mutect2, pindel, varscan2
- CCDC81 | c.1187G>T p.R396I (on ENST00000445632 / NM_001156474.2; = p.R306I on NM_021827.4) | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CDKL5 | c.797T>C p.L266S | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- CHST4 | c.1159T>G p.*387Eext*3 | Nonstop Mutation (SNP) | VAF 25/413 reads (6%) | called by muse, mutect2
- CR2 | c.2329C>A p.P777T | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSNK1G3 | c.829T>C p.C277R | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSPG5 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- DST | c.19918G>C p.E6640Q (on ENST00000361203 / NM_001374722.1; = p.E4337Q on NM_015548.5) | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- FBXO21 | c.1539G>A p.R513= (on ENST00000330622 / NM_033624.3; = p.R506= on NM_015002.3) | Splice Region (SNP) | VAF 19/118 reads (16%) | called by muse, mutect2, varscan2
- FREM3 | c.4805A>C p.N1602T | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- GABRA6 | c.732G>T p.M244I | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GPM6A | c.415T>G p.L139V | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GPRC6A | c.1084T>A p.S362T | Missense Mutation (SNP) | VAF 35/238 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- H3C2 | c.8G>C p.R3P | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HEPACAM2 | c.374A>C p.N125T (on ENST00000394468 / NM_001039372.4; = p.N113T on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2
- KCNK7 | c.493A>T p.R165W | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LAMP2 | c.1049T>A p.L350Q | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC53 | c.1533A>T p.K511N | Missense Mutation (SNP) | VAF 57/232 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- MARCO | c.1108+1G>C p.X370_splice | Splice Site (SNP) | VAF 34/264 reads (13%) | called by muse, mutect2, varscan2
- MYH11 | c.944T>C p.V315A | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- PDE10A | c.2115A>C p.K705N | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- PDIA6 | c.934G>T p.G312C | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT tolerated (0.66); PolyPhen probably damaging (1); called by muse, mutect2
- PIK3C2G | c.2247A>C p.E749D (on ENST00000676171; = p.E708D on NM_004570.5) | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PPP1R3A | c.1397T>G p.L466R | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- PRPF8 | c.2648G>A p.R883H | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SEL1L3 | c.2861G>A p.G954E | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEMA3E | c.1474A>C p.I492L | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2
- SHTN1 | c.1129A>G p.I377V | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- SIM1 | c.968A>C p.H323P | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLC7A7 | c.680A>T p.D227V | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.219); called by muse, mutect2
- SLCO3A1 | c.646G>T p.G216* | Nonsense Mutation (SNP) | VAF 39/153 reads (25%) | called by muse, mutect2, varscan2
- SUPT20HL2 | c.2278C>T p.P760S | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TADA3 | c.50_60del p.V17Efs*14 | Frame Shift Del (DEL) | VAF 31/190 reads (16%) | called by mutect2, pindel, varscan2
- TCEA3 | c.439del p.E147Kfs*20 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | called by mutect2, pindel*, varscan2
- TENM4 | c.3623G>A p.G1208D | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRAM1L1 | c.731A>G p.E244G | Missense Mutation (SNP) | VAF 65/286 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- UGGT2 | c.2068A>C p.N690H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2
- USP48 | c.1451-3C>T | Splice Region (SNP) | VAF 40/237 reads (17%) | called by muse, mutect2, varscan2
- YES1 | c.1425T>C p.G475= | Splice Region (SNP) | VAF 22/155 reads (14%) | called by mutect2, varscan2
- ZNF239 | c.818C>T p.T273I | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF574 | c.178A>G p.T60A | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACSM1 | c.423G>A p.A141= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as rs764978151; called by mutect2, varscan2
- CWF19L1 | c.600C>G p.T200= | Silent (SNP) | VAF 30/196 reads (15%) | called by muse, mutect2, varscan2
- DNAH9 | c.2847T>C p.V949= | Silent (SNP) | VAF 21/124 reads (17%) | called by muse, mutect2, varscan2
- H1-5 | c.288G>C p.L96= | Silent (SNP) | VAF 16/152 reads (11%) | catalogued as rs777080218; called by muse, mutect2
- IGLV3-1 | c.136T>C p.L46= | Silent (SNP) | VAF 68/138 reads (49%) | catalogued as rs374795971; called by muse, varscan2
- KNDC1 | c.3150T>C p.A1050= | Silent (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- NALCN | c.1518T>C p.L506= | Silent (SNP) | VAF 47/247 reads (19%) | called by muse, mutect2, varscan2
- PCDHGA10 | c.1152A>G p.G384= | Silent (SNP) | VAF 14/160 reads (9%) | called by muse, mutect2
- RAD17 | c.591A>G p.K197= (on ENST00000380774 / NM_133339.2; = p.K186= on NM_002873.1) | Silent (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- TBC1D9B | c.762C>T p.D254= | Silent (SNP) | VAF 13/58 reads (22%) | called by muse, mutect2, varscan2
- ZNF571 | c.666T>G p.P222= | Silent (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- ARHGEF38 | c.*415T>G | 3'UTR (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- ATOX1 | chr5:151758708 del CG | 5'Flank (DEL) | VAF 11/55 reads (20%) | called by mutect2, pindel, varscan2
- BCL7A | chr12:122021513 G>T | 5'Flank (SNP) | VAF 49/126 reads (39%) | catalogued as COSV55848479; called by muse, mutect2, varscan2
- BEND4 | c.*654C>A | 3'UTR (SNP) | VAF 8/61 reads (13%) | called by muse, mutect2, varscan2
- BROX | c.*1109A>G | 3'UTR (SNP) | VAF 17/119 reads (14%) | called by muse, mutect2, varscan2
- CAMK4 | c.*9046C>T | 3'UTR (SNP) | VAF 21/90 reads (23%) | called by muse, mutect2, varscan2
- CD8B2 | c.620+2682A>C | Intron (SNP) | VAF 89/266 reads (33%) | called by muse, mutect2, varscan2
- CDS2 | c.*7516G>A | 3'UTR (SNP) | VAF 12/108 reads (11%) | catalogued as rs1157447487; called by muse, mutect2, varscan2
- CFAP43 | c.1443-253C>A | Intron (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- DCP1B | c.1525-988T>C | Intron (SNP) | VAF 24/156 reads (15%) | called by muse, mutect2, varscan2
- DDAH1 | c.*1870T>C | 3'UTR (SNP) | VAF 16/83 reads (19%) | called by muse, mutect2, varscan2
- DHCR7 | c.*72C>G | 3'UTR (SNP) | VAF 74/205 reads (36%) | called by muse, mutect2, varscan2
- DMAC2L | c.-559C>G | 5'UTR (SNP) | VAF 42/230 reads (18%) | called by muse, mutect2
- DNM3 | chr1:172411258 C>T | 3'Flank (SNP) | VAF 6/63 reads (10%) | called by muse, mutect2
- DSC1 | c.2487+72del | Intron (DEL) | VAF 15/62 reads (24%) | called by mutect2, pindel
- DUS4L-BCAP29 | c.-110-59C>G | Intron (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2
- EI24P4 | n.856T>C | RNA (SNP) | VAF 65/199 reads (33%) | catalogued as rs780205588; called by muse, mutect2, varscan2
- EIF3E | c.*90A>G | 3'UTR (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2, varscan2
- FSHB | c.*971A>C | 3'UTR (SNP) | VAF 7/50 reads (14%) | called by mutect2, varscan2
- GABRG2 | c.*1062G>A | 3'UTR (SNP) | VAF 16/55 reads (29%) | called by muse, mutect2, varscan2
- GMPPA | c.138+25C>G | Intron (SNP) | VAF 42/306 reads (14%) | called by muse, mutect2, varscan2
- GPCPD1 | c.*519A>G | 3'UTR (SNP) | VAF 20/218 reads (9%) | called by muse, mutect2
- GPR26 | c.*2245T>C | 3'UTR (SNP) | VAF 26/128 reads (20%) | called by muse, mutect2, varscan2
- GRAMD1A | chr19:34996234 C>T | 5'Flank (SNP) | VAF 18/192 reads (9%) | called by muse, mutect2
- HGF | c.89-65T>C | Intron (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- HIPK2 | c.*3475A>T | 3'UTR (SNP) | VAF 30/128 reads (23%) | called by muse, mutect2, varscan2
- INPP5F | c.1887-2142G>A | Intron (SNP) | VAF 16/101 reads (16%) | called by muse, mutect2, varscan2
- ISX | c.-205G>A | 5'UTR (SNP) | VAF 39/242 reads (16%) | called by muse, mutect2, varscan2
- ITIH5 | c.*2116A>T | 3'UTR (SNP) | VAF 4/44 reads (9%) | catalogued as rs1353802215; called by mutect2, varscan2
- KCNA4 | c.-563T>G | 5'UTR (SNP) | VAF 7/76 reads (9%) | catalogued as COSV60256085; called by muse, mutect2
- KIAA0100 | c.1229+25C>G | Intron (SNP) | VAF 17/141 reads (12%) | called by muse, mutect2, varscan2
- LINC01546 | n.213A>G | RNA (SNP) | VAF 88/135 reads (65%) | called by muse, mutect2, varscan2
- MEI1 | chr22:41696788 G>A | 5'Flank (SNP) | VAF 21/97 reads (22%) | called by muse, mutect2, varscan2
- NACC2 | c.*1725C>G | 3'UTR (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- NLRP3 | chr1:247449011 A>T | 3'Flank (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2
- PAX3 | c.586+405C>T | Intron (SNP) | VAF 38/298 reads (13%) | catalogued as rs779755467, COSV99286777; called by muse, mutect2, varscan2
- PBX1 | c.265+27074A>G | Intron (SNP) | VAF 28/65 reads (43%) | catalogued as rs929479855; called by muse, mutect2, varscan2
- PLD2 | c.*377A>G | 3'UTR (SNP) | VAF 37/184 reads (20%) | catalogued as rs1220374321; called by muse, mutect2, varscan2
- PSD3 | c.*8333T>G | 3'UTR (SNP) | VAF 4/72 reads (6%) | called by muse, mutect2
- PTK2 | c.2710-1169T>C | Intron (SNP) | VAF 24/125 reads (19%) | called by muse, mutect2, varscan2
- S100A7A | chr1:153420535 A>C | 3'Flank (SNP) | VAF 9/128 reads (7%) | called by muse, mutect2
- SGIP1 | c.*1035del | 3'UTR (DEL) | VAF 24/83 reads (29%) | catalogued as rs575082820; called by mutect2, varscan2
- SLC36A1 | c.*1991C>T | 3'UTR (SNP) | VAF 12/110 reads (11%) | called by muse, mutect2, varscan2
- SLC4A11 | c.1464-67C>A | Intron (SNP) | VAF 11/43 reads (26%) | called by muse, mutect2
- STON2 | c.2784+81C>A | Intron (SNP) | VAF 31/267 reads (12%) | called by muse, mutect2, varscan2
- STPG2 | c.*2972T>G | 3'UTR (SNP) | VAF 14/53 reads (26%) | called by muse, varscan2
- STRA6 | c.1300+35C>T | Intron (SNP) | VAF 3/52 reads (6%) | called by muse, mutect2
- SUCO | chr1:172532622 G>A | 5'Flank (SNP) | VAF 15/277 reads (5%) | called by muse, mutect2
- SV2C | c.*5095T>G | 3'UTR (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- SYTL2 | c.1562-356G>A | Intron (SNP) | VAF 27/227 reads (12%) | called by muse, mutect2, varscan2
- UBASH3B | c.*2307A>G | 3'UTR (SNP) | VAF 29/102 reads (28%) | called by muse, mutect2, varscan2
- YLPM1 | c.6111+27C>A | Intron (SNP) | VAF 43/181 reads (24%) | called by muse, mutect2, varscan2
- ZNF391 | c.*1558A>T | 3'UTR (SNP) | VAF 11/90 reads (12%) | called by muse, mutect2, varscan2
- ZNF716 | c.*2397G>A | 3'UTR (SNP) | VAF 15/70 reads (21%) | catalogued as rs1295001821; called by muse, mutect2, varscan2
